Somatic mutation profile of tumor specimen TCGA-DD-A3A7-01A (aliquot TCGA-DD-A3A7-01A-11D-A22F-10) from TCGA case TCGA-DD-A3A7, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Age at diagnosis: 67.3 years (24,599 days).
Specimen TCGA-DD-A3A7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dbde0e08-e7e6-4684-ba7f-34e9a8cf6db7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A3A7-11A (Solid Tissue Normal), aliquot TCGA-DD-A3A7-11A-11D-A22F-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8568142c-5506-4233-a32e-b1285bd7db5e

The open-access MAF lists 149 somatic variants for this specimen: 104 protein-altering or splice-affecting, 31 silent, 14 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 31, Intron 6, Splice Site 6, Nonsense Mutation 5, Frame Shift Ins 4, Frame Shift Del 3, 3'UTR 3, 3'Flank 2, RNA 2, In Frame Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KMT2D | c.16412+1G>T p.X5471_splice | Splice Site (SNP) | VAF 17/83 reads (20%) | catalogued as rs794727752, CS122132, COSV56451637, COSV56483250; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.405C>A p.C135* | Nonsense Mutation (SNP) | VAF 16/22 reads (73%) | hotspot (GDC flag); catalogued as COSV52665429, COSV52669330, COSV52682693, COSV52815283; called by muse, mutect2, varscan2
- ADAM17 | c.2387C>T p.T796M | Missense Mutation (SNP) | VAF 61/132 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); catalogued as rs572250428, COSV60398595; called by muse, mutect2, varscan2
- ADAM22 | c.1579A>T p.I527F | Missense Mutation (SNP) | VAF 80/213 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.129); catalogued as COSV55979889; called by muse, mutect2, varscan2
- ALMS1 | c.5974C>A p.H1992N | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.104); catalogued as COSV52512269; called by mutect2, varscan2
- ALMS1 | c.6077A>G p.K2026R | Missense Mutation (SNP) | VAF 32/80 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as rs367904732; called by muse, varscan2
- ALMS1 | c.6144T>A p.Y2048* | Nonsense Mutation (SNP) | VAF 34/85 reads (40%) | catalogued as COSV52512288; called by muse, varscan2
- ASAP2 | c.1511G>A p.C504Y | Missense Mutation (SNP) | VAF 29/74 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV55633304; called by muse, mutect2, varscan2
- ATF7IP | c.2942-1G>T p.X981_splice | Splice Site (SNP) | VAF 20/35 reads (57%) | catalogued as COSV99661775; called by muse, mutect2, varscan2
- AUTS2 | c.947G>A p.R316Q | Missense Mutation (SNP) | VAF 11/63 reads (17%) | SIFT tolerated (0.51); PolyPhen benign (0); catalogued as rs772514731, COSV61409708; called by muse, mutect2, varscan2
- BECN1 | c.1208T>C p.I403T | Missense Mutation (SNP) | VAF 30/44 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100162102, COSV59312122; called by muse, mutect2, varscan2
- BMP3 | c.604A>G p.I202V | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT tolerated (0.06); PolyPhen benign (0.114); catalogued as COSV51086996; called by muse, mutect2, varscan2
- BRD4 | c.1369A>T p.M457L | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.047); catalogued as COSV54587850; called by muse, mutect2, varscan2
- BRWD1 | c.2111A>G p.N704S | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.146); catalogued as COSV60897589; called by muse, mutect2, varscan2
- C16orf89 | c.519C>G p.S173R | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT deleterious (0.05); PolyPhen benign (0.416); catalogued as COSV60124301; called by muse, mutect2, varscan2
- CABIN1 | c.5732A>G p.H1911R | Missense Mutation (SNP) | VAF 18/22 reads (82%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.084); catalogued as COSV54083507; called by muse, mutect2, varscan2
- CCAR1 | c.827-1G>T p.X276_splice | Splice Site (SNP) | VAF 23/47 reads (49%) | catalogued as COSV99771107; called by muse, mutect2, varscan2
- CDH6 | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.4); PolyPhen benign (0.021); catalogued as rs1561061837, COSV54071866; called by muse, mutect2
- CEACAM5 | c.1856C>T p.S619F | Missense Mutation (SNP) | VAF 68/154 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55752716; called by muse, mutect2, varscan2
- CGAS | c.648G>T p.E216D | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV64808353; called by muse, mutect2, varscan2
- COBL | c.1475C>G p.T492S | Missense Mutation (SNP) | VAF 51/195 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.77); catalogued as COSV54348597; called by muse, mutect2, varscan2
- DIXDC1 | c.734T>C p.V245A (on ENST00000440460 / NM_001037954.4; = p.V34A on NM_033425.4) | Missense Mutation (SNP) | VAF 31/69 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.067); catalogued as COSV59462301; called by muse, mutect2, varscan2
- DMXL2 | c.591G>A p.W197* | Nonsense Mutation (SNP) | VAF 14/66 reads (21%) | catalogued as COSV51848450, COSV51849829; called by muse, mutect2, varscan2
- DNHD1 | c.8900C>T p.P2967L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54437672; called by muse, mutect2, varscan2
- DSEL | c.3628A>T p.T1210S | Missense Mutation (SNP) | VAF 34/100 reads (34%) | SIFT tolerated (0.88); PolyPhen possibly damaging (0.529); catalogued as rs1219183760, COSV59492260; called by muse, mutect2, varscan2
- ETF1 | c.1286A>T p.D429V | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.012); catalogued as COSV62127557; called by muse, mutect2, varscan2
- EVC2 | c.3184G>T p.G1062W | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.787); catalogued as rs1237759012, COSV60395530; called by muse, mutect2, varscan2
- FAM122A | c.569C>A p.P190H | Missense Mutation (SNP) | VAF 47/111 reads (42%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV55250129; called by muse, mutect2, varscan2
- FLG | c.8047G>A p.G2683R | Missense Mutation (SNP) | VAF 45/261 reads (17%) | SIFT tolerated (0.87); PolyPhen benign (0.026); catalogued as rs978966210, COSV100911660; called by muse, mutect2, varscan2
- GIN1 | c.484A>G p.I162V | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV67536953; called by muse, mutect2, varscan2
- GLB1L3 | c.714G>A p.M238I | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.665); catalogued as COSV66282038; called by muse, mutect2, varscan2
- GLG1 | c.3383C>T p.A1128V | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.48); PolyPhen benign (0.027); catalogued as COSV52668794; called by muse, mutect2, varscan2
- GON4L | c.262A>C p.N88H | Missense Mutation (SNP) | VAF 32/379 reads (8%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV55195749; called by muse, mutect2
- GRIA4 | c.1337A>G p.Y446C | Missense Mutation (SNP) | VAF 31/78 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV56902256; called by muse, mutect2, varscan2
- GTSF1L | c.96G>C p.K32N | Missense Mutation (SNP) | VAF 35/141 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV65932488, COSV65932616, COSV65932796; called by muse, mutect2, varscan2
- HK3 | c.2578C>A p.L860M | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.971); catalogued as COSV52841240; called by muse, mutect2, varscan2
- HRH3 | c.551C>G p.P184R | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.327); catalogued as COSV58048976; called by muse, mutect2, varscan2
- HRNR | c.3050G>C p.G1017A | Missense Mutation (SNP) | VAF 22/268 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.207); catalogued as rs765947560, COSV64259190; called by muse, mutect2
- INTS1 | c.3013G>T p.D1005Y | Missense Mutation (SNP) | VAF 31/44 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs760716820, COSV67177935; called by muse, mutect2, varscan2
- IQCA1 | c.2428G>A p.G810S | Missense Mutation (SNP) | VAF 63/75 reads (84%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as rs754443986, COSV54504253; called by muse, mutect2, varscan2
- IRAK1 | c.1984A>G p.I662V | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.984); catalogued as rs782334259, COSV64109993; called by muse, mutect2, varscan2
- JMY | c.2217A>C p.E739D | Missense Mutation (SNP) | VAF 68/156 reads (44%) | SIFT tolerated (0.41); PolyPhen benign (0.023); catalogued as COSV68661264; called by muse, mutect2, varscan2
- KCNAB1 | c.922G>A p.G308R (on ENST00000490337 / NM_172160.3; = p.G297R on NM_003471.3) | Missense Mutation (SNP) | VAF 33/69 reads (48%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as rs370046885; called by muse, mutect2, varscan2
- KDM8 | c.665+1G>C p.X222_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as COSV53730089; called by muse, mutect2, varscan2
- KIF22 | c.1606C>G p.L536V | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT tolerated (0.85); PolyPhen benign (0.012); catalogued as COSV99361226; called by muse, mutect2
- KIR2DL3 | c.130A>G p.T44A | Missense Mutation (SNP) | VAF 46/62 reads (74%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV60898240; called by muse, mutect2, varscan2
- KLHL7 | c.1250T>C p.L417P (on ENST00000339077 / NM_001031710.3; = p.L369P on NM_018846.5) | Missense Mutation (SNP) | VAF 30/153 reads (20%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.994); catalogued as COSV59162166; called by muse, mutect2, varscan2
- KRTAP10-7 | c.1103C>T p.S368F | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV59110874; called by muse, mutect2, varscan2
- KRTAP4-2 | c.57C>G p.N19K | Missense Mutation (SNP) | VAF 35/135 reads (26%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as COSV66658623; called by muse, mutect2, varscan2
- LACTB | c.906T>G p.I302M | Missense Mutation (SNP) | VAF 41/98 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.113); catalogued as COSV56056161; called by muse, mutect2, varscan2
- LGALS4 | c.451G>A p.G151R | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs760505571, COSV57044049; called by muse, mutect2
- LMF1 | c.1632C>A p.F544L | Missense Mutation (SNP) | VAF 15/32 reads (47%) | SIFT tolerated (0.57); PolyPhen benign (0.042); catalogued as COSV51898133; called by muse, mutect2, varscan2
- LRRK2 | c.2713A>T p.K905* | Nonsense Mutation (SNP) | VAF 99/134 reads (74%) | catalogued as COSV54156711; called by muse, mutect2, varscan2
- MYCBP2 | c.6122A>G p.Y2041C (on ENST00000357337; = p.Y2079C on NM_015057.5) | Missense Mutation (SNP) | VAF 45/164 reads (27%) | SIFT tolerated (0.13); PolyPhen benign (0.156); catalogued as rs754388017, COSV62023571; called by muse, mutect2, varscan2
- MYOD1 | c.654C>A p.S218R | Missense Mutation (SNP) | VAF 23/38 reads (61%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.806); catalogued as rs762738028, COSV51453945; called by muse, mutect2, varscan2
- NACAD | c.1225C>T p.P409S | Missense Mutation (SNP) | VAF 20/76 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); catalogued as COSV71989508; called by muse, mutect2, varscan2
- NCAPG | c.2548T>C p.Y850H | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as COSV52270847; called by muse, mutect2, varscan2
- NLRC5 | c.82C>A p.L28M | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.264); catalogued as COSV52657171; called by muse, mutect2, varscan2
- NPVF | c.138+1G>A p.X46_splice | Splice Site (SNP) | VAF 63/241 reads (26%) | catalogued as COSV56060857; called by muse, mutect2, varscan2
- NRDC | c.2258A>G p.N753S | Missense Mutation (SNP) | VAF 79/202 reads (39%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV61405376; called by muse, mutect2, varscan2
- NUDT10 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 33/44 reads (75%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV62854278; called by muse, mutect2, varscan2
- OR5T3 | c.241T>A p.L81M | Missense Mutation (SNP) | VAF 59/151 reads (39%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.873); catalogued as COSV57381166; called by muse, mutect2, varscan2
- OR9Q1 | c.454G>T p.G152C | Missense Mutation (SNP) | VAF 56/142 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59041704; called by muse, mutect2, varscan2
- PARP12 | c.587A>G p.K196R | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV54935073; called by muse, mutect2, varscan2
- PBX1 | c.1081G>A p.A361T | Missense Mutation (SNP) | VAF 23/151 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV63344987; called by muse, mutect2, varscan2
- PCDHA13 | c.1390G>A p.V464M | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.987); catalogued as COSV56487736; called by muse, mutect2
- PCDHGA3 | c.502C>A p.Q168K | Missense Mutation (SNP) | VAF 34/145 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.178); catalogued as rs768252153, COSV53966775, COSV54001987; called by muse, mutect2, varscan2
- PDZRN4 | c.1429A>G p.K477E (on ENST00000402685 / NM_001164595.2; = p.K219E on NM_013377.4) | Missense Mutation (SNP) | VAF 62/93 reads (67%) | SIFT tolerated (0.1); PolyPhen benign (0.248); catalogued as rs755567199, COSV54204894; called by muse, mutect2, varscan2
- PLCB1 | c.1389G>T p.L463F | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62055964; called by muse, mutect2, varscan2
- PPL | c.3475T>C p.W1159R | Missense Mutation (SNP) | VAF 24/64 reads (38%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs762357647, COSV52169049; called by muse, mutect2, varscan2
- PRDM5 | c.865+1G>T p.X289_splice | Splice Site (SNP) | VAF 34/81 reads (42%) | catalogued as COSV53361986; called by muse, mutect2, varscan2
- PTPRM | c.518A>C p.D173A | Missense Mutation (SNP) | VAF 54/162 reads (33%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.991); catalogued as COSV59864459; called by muse, mutect2, varscan2
- RASA1 | c.3037A>G p.S1013G | Missense Mutation (SNP) | VAF 30/111 reads (27%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.841); catalogued as rs993477801, COSV56924471; called by muse, mutect2, varscan2
- RECQL4 | c.2654T>C p.L885P | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as COSV56741454; called by muse, mutect2, varscan2
- REPS2 | c.1814C>T p.S605F | Missense Mutation (SNP) | VAF 4/74 reads (5%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.866); catalogued as COSV58183616; called by muse, mutect2
- RNF175 | c.340G>A p.V114I | Missense Mutation (SNP) | VAF 29/60 reads (48%) | SIFT tolerated (0.58); PolyPhen benign (0.003); catalogued as rs370409419; called by muse, mutect2, varscan2
- RPH3A | c.426C>G p.I142M (on ENST00000389385 / NM_001143854.2; = p.I138M on NM_014954.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV66991579; called by muse, mutect2, varscan2
- SLC26A1 | c.1948A>C p.S650R | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as COSV56103998; called by muse, mutect2, varscan2
- SLC29A2 | c.658C>T p.R220C | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); catalogued as rs962219949, COSV60802980; called by muse, mutect2, varscan2
- SLC30A8 | c.479A>G p.Y160C | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV69971898; called by mutect2, varscan2
- SLC39A12 | c.412A>G p.K138E | Missense Mutation (SNP) | VAF 60/135 reads (44%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as COSV66199236; called by muse, mutect2, varscan2
- SLC4A10 | c.2039T>G p.L680W (on ENST00000446997 / NM_001354461.2; = p.L650W on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.895); catalogued as COSV55783555; called by muse, mutect2, varscan2
- SPATA1 | c.1137A>G p.I379M | Missense Mutation (SNP) | VAF 38/151 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747650691; called by muse, varscan2
- TAF3 | c.965A>G p.K322R | Missense Mutation (SNP) | VAF 17/40 reads (43%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.141); catalogued as rs1315842403, COSV60207535; called by muse, mutect2, varscan2
- THAP12 | c.937A>G p.M313V | Missense Mutation (SNP) | VAF 122/321 reads (38%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs148924079; called by muse, mutect2, varscan2
- TUBA3C | c.1196A>G p.Y399C | Missense Mutation (SNP) | VAF 32/104 reads (31%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.989); catalogued as COSV68028701; called by muse, mutect2, varscan2
- USP35 | c.1672C>A p.P558T | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.51); PolyPhen benign (0.014); catalogued as rs202205531, COSV71572992; called by muse, mutect2, varscan2
- WASF2 | c.1400A>G p.N467S | Missense Mutation (SNP) | VAF 34/83 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV71005789; called by muse, mutect2, varscan2
- WDFY2 | c.544C>A p.L182I | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.952); catalogued as COSV53290475; called by muse, mutect2, varscan2
- YWHAE | c.540C>A p.F180L | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV51983169; called by muse, mutect2, varscan2
- ZFP37 | c.1777C>T p.R593* | Nonsense Mutation (SNP) | VAF 37/100 reads (37%) | catalogued as rs373174435; called by muse, mutect2, varscan2
- ZNF226 | c.2096A>G p.Y699C | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1484884127, COSV56196909; called by muse, mutect2, varscan2
- APOB | c.1788dup p.I597Yfs*53 | Frame Shift Ins (INS) | VAF 43/127 reads (34%) | called by mutect2, pindel, varscan2
- ATF7IP | c.2942A>C p.D981A | Missense Mutation (SNP) | VAF 20/35 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- CCAR1 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD109 | c.2003del p.N668Mfs*6 | Frame Shift Del (DEL) | VAF 27/87 reads (31%) | called by mutect2, pindel, varscan2
- GGNBP2 | c.947A>T p.K316M | Missense Mutation (SNP) | VAF 37/189 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- IMMP1L | c.135dup p.Q46Sfs*12 | Frame Shift Ins (INS) | VAF 98/300 reads (33%) | called by mutect2, pindel, varscan2
- NPAT | c.187_196del p.L63Mfs*2 | Frame Shift Del (DEL) | VAF 67/203 reads (33%) | called by mutect2, pindel, varscan2
- OR5T2 | c.221_226del p.Y74_L75del | In Frame Del (DEL) | VAF 17/68 reads (25%) | called by mutect2, pindel, varscan2
- POM121C | c.1463T>C p.L488P (on ENST00000607367; = p.L246P on NM_001099415.3) | Missense Mutation (SNP) | VAF 66/237 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SENP6 | c.1047_1048delinsTTTC p.E349Dfs*23 | Frame Shift Ins (INS) | VAF 20/45 reads (44%) | called by pindel, varscan2*
- SPATA1 | c.1149_1159del p.E384Cfs*3 | Frame Shift Del (DEL) | VAF 36/150 reads (24%) | called by pindel, varscan2
- TTC9 | c.276_277insA p.P93Tfs*50 | Frame Shift Ins (INS) | VAF 8/10 reads (80%) | called by mutect2, varscan2
- ADGRB2 | c.1923C>T p.D641= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as COSV57074583; called by muse, mutect2, varscan2
- AP1B1 | c.2814C>T p.H938= | Silent (SNP) | VAF 15/33 reads (45%) | catalogued as rs147684584; called by muse, mutect2, varscan2
- ARHGEF7 | c.1398C>A p.I466= (on ENST00000375741 / NM_001113511.2; = p.I288= on NM_003899.5 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 30/112 reads (27%) | catalogued as COSV54545015; called by muse, mutect2, varscan2
- CASP8AP2 | c.78T>C p.D26= | Silent (SNP) | VAF 67/157 reads (43%) | catalogued as COSV52747827; called by muse, mutect2, varscan2
- CLEC4F | c.1050C>T p.G350= | Silent (SNP) | VAF 68/174 reads (39%) | catalogued as COSV55479904; called by muse, mutect2, varscan2
- DNAH7 | c.9363A>G p.Q3121= | Silent (SNP) | VAF 39/127 reads (31%) | catalogued as COSV56769450; called by muse, mutect2, varscan2
- FOXI1 | c.894C>A p.P298= | Silent (SNP) | VAF 29/125 reads (23%) | catalogued as COSV60388878; called by muse, mutect2, varscan2
- GPHN | c.354A>T p.G118= | Silent (SNP) | VAF 29/42 reads (69%) | catalogued as COSV59483180; called by muse, mutect2, varscan2
- HSPA8 | c.186C>T p.N62= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV57084338; called by muse, mutect2, varscan2
- IQCF1 | c.78T>C p.H26= | Silent (SNP) | VAF 80/232 reads (34%) | catalogued as COSV58823582; called by muse, mutect2, varscan2
- LCE6A | c.54C>T p.S18= | Silent (SNP) | VAF 42/204 reads (21%) | catalogued as rs1383628188, COSV70391171; called by muse, mutect2, varscan2
- MYO9A | c.322A>C p.R108= | Silent (SNP) | VAF 47/100 reads (47%) | catalogued as COSV61852669; called by muse, mutect2, varscan2
- NUP133 | c.483T>C p.S161= | Silent (SNP) | VAF 21/98 reads (21%) | catalogued as COSV54572387; called by muse, mutect2, varscan2
- NXF3 | c.1506C>G p.T502= | Silent (SNP) | VAF 29/36 reads (81%) | catalogued as COSV67704051; called by muse, mutect2, varscan2
- OR6K2 | c.877C>T p.L293= | Silent (SNP) | VAF 153/229 reads (67%) | catalogued as rs1553241072, COSV100656920, COSV62743615; called by muse, mutect2, varscan2
- OXSM | c.969T>A p.G323= | Silent (SNP) | VAF 5/16 reads (31%) | catalogued as COSV55001892; called by muse, mutect2, varscan2
- PALB2 | c.1551A>G p.K517= | Silent (SNP) | VAF 55/127 reads (43%) | catalogued as rs755845383, COSV55166100; called by muse, mutect2, varscan2
- PCDHA4 | c.567A>G p.V189= | Silent (SNP) | VAF 46/184 reads (25%) | catalogued as COSV63542694; called by muse, mutect2, varscan2
- PLA2R1 | c.2398A>C p.R800= | Silent (SNP) | VAF 40/168 reads (24%) | catalogued as COSV51780660; called by muse, mutect2, varscan2
- RAVER2 | c.1839C>T p.S613= (on ENST00000294428 / NM_001366165.1; = p.S600= on NM_018211.4) | Silent (SNP) | VAF 15/46 reads (33%) | catalogued as COSV53808074; called by muse, mutect2, varscan2
- RBM39 | c.684A>G p.S228= | Silent (SNP) | VAF 70/117 reads (60%) | catalogued as COSV53615859; called by muse, mutect2, varscan2
- RNF20 | c.375A>G p.K125= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV100874324; called by muse, mutect2
- STARD13 | c.3096C>G p.L1032= (on ENST00000336934 / NM_001243476.3; = p.L914= on NM_052851.3) | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV55232289; called by muse, mutect2, varscan2
- STX16 | c.957C>T p.L319= (on ENST00000371141 / NM_001001433.3; = p.L298= on NM_003763.6) | Silent (SNP) | VAF 52/195 reads (27%) | catalogued as COSV56606525; called by muse, mutect2, varscan2
- TAS2R38 | c.921T>A p.A307= | Silent (SNP) | VAF 22/63 reads (35%) | catalogued as COSV71885600; called by muse, mutect2, varscan2
- TENM2 | c.1041C>G p.P347= (on ENST00000518659 / NM_001122679.2; = p.P156= on NM_001080428.3) | Silent (SNP) | VAF 49/114 reads (43%) | catalogued as rs1382783947, COSV69133103; called by muse, mutect2, varscan2
- TPPP3 | c.48G>A p.K16= | Silent (SNP) | VAF 11/51 reads (22%) | catalogued as rs778166680, COSV52084079; called by muse, mutect2, varscan2
- TTN | c.30252T>C p.Y10084= (on ENST00000591111; = p.Y9157= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 75/329 reads (23%) | catalogued as COSV60128543; called by muse, mutect2, varscan2
- USP5 | c.2169T>G p.P723= (on ENST00000229268 / NM_001098536.2; = p.P700= on NM_003481.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 13/19 reads (68%) | catalogued as COSV57537997; called by muse, mutect2, varscan2
- ZHX2 | c.186G>A p.E62= | Silent (SNP) | VAF 15/81 reads (19%) | catalogued as COSV58714095; called by muse, mutect2, varscan2
- ZNF786 | c.2140C>A p.R714= | Silent (SNP) | VAF 44/114 reads (39%) | catalogued as COSV60275107, COSV60276566; called by muse, mutect2, varscan2
- AP1B1 | c.1060-98A>C | Intron (SNP) | VAF 19/45 reads (42%) | called by muse, mutect2, varscan2
- CXCR2 | c.*1015A>G | 3'UTR (SNP) | VAF 3/40 reads (8%) | called by muse, mutect2
- DYRK2 | c.*967G>A | 3'UTR (SNP) | VAF 120/170 reads (71%) | catalogued as COSV100165325; called by muse, mutect2, varscan2
- FADS3 | c.748-14G>A | Intron (SNP) | VAF 17/62 reads (27%) | catalogued as rs377717074; called by muse, mutect2, varscan2
- FAM110A | c.-98+3505A>G | Intron (SNP) | VAF 7/20 reads (35%) | called by muse, mutect2, varscan2
- H2AZ1 | c.3+49G>T | Intron (SNP) | VAF 13/25 reads (52%) | called by muse, varscan2
- KRT5 | c.1474+21A>G | Intron (SNP) | VAF 30/179 reads (17%) | called by muse, mutect2, varscan2
- KRTAP4-1 | c.-189T>A | 5'UTR (SNP) | VAF 83/418 reads (20%) | catalogued as COSV100569657; called by mutect2, varscan2
- LINC02724 | n.786A>G | RNA (SNP) | VAF 4/36 reads (11%) | catalogued as rs1425653712; called by muse, mutect2
- LINC02876 | n.278G>T | RNA (SNP) | VAF 58/244 reads (24%) | called by muse, mutect2, varscan2
- MIR600 | chr9:123111401 A>G | 3'Flank (SNP) | VAF 16/35 reads (46%) | called by muse, mutect2, varscan2
- ODF2L | chr1:86348762 T>G | 3'Flank (SNP) | VAF 67/167 reads (40%) | catalogued as COSV54016067; called by muse, mutect2, varscan2
- PABPC3 | c.*719dup | 3'UTR (INS) | VAF 46/110 reads (42%) | called by mutect2, pindel, varscan2
- PLCXD2 | c.866+6643C>G | Intron (SNP) | VAF 37/96 reads (39%) | catalogued as COSV101210090; called by muse, mutect2, varscan2
